Somatic mutation profile of tumor specimen TCGA-44-A47A-01A (aliquot TCGA-44-A47A-01A-21D-A24D-08) from TCGA case TCGA-44-A47A, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.8 years (28,782 days).
Specimen TCGA-44-A47A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bb8fba9-106c-4b35-9cfc-00253560b361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-A47A-10A (Blood Derived Normal), aliquot TCGA-44-A47A-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2baaf2a0-99ab-4e08-b408-0ec354dae20f

The open-access MAF lists 225 somatic variants for this specimen: 183 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 38, Nonsense Mutation 12, Frame Shift Del 7, Splice Site 4, Nonstop Mutation 2, RNA 2, Splice Region 1, Frame Shift Ins 1, In Frame Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV100494177; called by muse, mutect2, varscan2
- ADGRA3 | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV99293268; called by muse, varscan2
- ANK2 | c.8012C>T p.A2671V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV100001596; called by muse, mutect2, varscan2
- ARAP2 | c.4651C>T p.R1551C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs775209671, COSV100394643; called by muse, mutect2, varscan2
- ARHGAP27 | c.1927G>C p.E643Q (on ENST00000428638 / NM_001282290.1; = p.E302Q on NM_199282.3) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV65358455; called by muse, mutect2, varscan2
- ASB6 | c.880G>C p.A294P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99475721; called by muse, mutect2, varscan2
- BAAT | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768526453, COSV52290567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACE2 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.171); catalogued as COSV100160801; called by muse, mutect2, varscan2
- BAIAP2L1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99134138; called by muse, mutect2
- BCAS1 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101006171; called by muse, mutect2, varscan2
- BCAS3 | c.1401T>G p.I467M | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101175909; called by muse, mutect2
- BRINP3 | c.2261del p.P754Qfs*55 | Frame Shift Del (DEL) | VAF 48/181 reads (27%) | catalogued as COSV66542840; called by mutect2, pindel, varscan2
- C6orf120 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV59324761; called by muse, mutect2, varscan2
- CACNB2 | c.691G>A p.G231S (on ENST00000324631 / NM_201596.3; = p.G176S on NM_000724.4) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as COSV99994521; called by muse, mutect2, varscan2
- CCAR1 | c.2539-1G>C p.X847_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99771024; called by muse, mutect2
- CCDC144A | c.1388C>A p.T463K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV100138530; called by muse, mutect2, varscan2
- CCDC80 | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV52815708, COSV99244758; called by muse, mutect2, varscan2
- CD163 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100775831; called by muse, mutect2, varscan2
- CDA | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV100906304; called by muse, mutect2, varscan2
- CEP128 | c.3052T>C p.Y1018H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs755751753, COSV55392783, COSV99824664; called by muse, mutect2, varscan2
- CEP63 | c.1394A>T p.Q465L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59677001; called by muse, mutect2, varscan2
- CHL1 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99851174; called by muse, mutect2
- CHRNA10 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs367930797; called by muse, mutect2, varscan2
- CKAP4 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 42/159 reads (26%) | catalogued as COSV100952451; called by muse, mutect2, varscan2
- CNTN3 | c.129T>A p.D43E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV55179778, COSV99724400; called by muse, mutect2, varscan2
- COG1 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100245307, COSV100245341; called by muse, mutect2
- COL11A2 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV100553994; called by muse, mutect2, varscan2
- CTCFL | c.1691A>T p.H564L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99712657; called by muse, mutect2, varscan2
- CUL9 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52725954; called by muse, mutect2
- DAD1 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as COSV99164714; called by muse, mutect2
- DNAH2 | c.2887C>T p.R963W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs368308627; called by muse, mutect2, varscan2
- DNAH9 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs201521165, COSV52333520; called by muse, mutect2, varscan2
- DNAJC6 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1322766445, COSV99674786; called by muse, mutect2, varscan2
- EIF2B1 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV99967567; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100349115; called by muse, mutect2, varscan2
- ELAVL4 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1355484430, COSV63916078; called by muse, mutect2
- ELMO1 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164490; called by muse, mutect2, varscan2
- EPHA2 | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781464115, COSV100626110; called by muse, mutect2, varscan2
- EPS15 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100869531; called by muse, mutect2
- FAM20A | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV56836572; called by muse, mutect2, varscan2
- FAM214B | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV100521310; called by muse, mutect2, varscan2
- FAM3D | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100716807; called by muse, mutect2, varscan2
- FBXW8 | c.160A>G p.R54G (on ENST00000309909; = p.R92G on NM_012174.1) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99997697; called by muse, mutect2, varscan2
- FIGLA | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV100189720; called by muse, mutect2
- FZD10 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99969413; called by muse, mutect2, varscan2
- GCLC | c.295G>T p.E99* (on ENST00000643939; = p.E103* on NM_001498.4) | Nonsense Mutation (SNP) | VAF 7/197 reads (4%) | catalogued as COSV99988622; called by muse, mutect2
- GEMIN5 | c.3541C>A p.Q1181K | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV99593878; called by muse, mutect2
- GJA9 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100668092; called by muse, mutect2, varscan2
- GNL3L | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV100328358; called by muse, mutect2, varscan2
- GPR32 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54513715; called by muse, mutect2
- GRIK5 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99490536; called by muse, mutect2, varscan2
- HEXA | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1209189473, COSV99173735; called by muse, mutect2, varscan2
- HLCS | c.1875G>T p.K625N | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100358202; called by muse, mutect2, varscan2
- HOXA11 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV99135969; called by muse, mutect2, varscan2
- HSD11B1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374552497; called by muse, mutect2, varscan2
- HSD17B1 | c.404C>G p.S135W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99864760; called by muse, mutect2, varscan2
- HTT | c.4246-1G>C p.X1416_splice | Splice Site (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100750748; called by muse, mutect2
- IBTK | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100090708; called by muse, mutect2, varscan2
- IDH3B | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as rs866647076, COSV100250098; called by muse, mutect2, varscan2
- IFNA1 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV99439895; called by muse, mutect2, varscan2
- IGF2BP1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99288645; called by muse, mutect2
- INTU | c.371del p.L124Yfs*19 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | catalogued as rs55831204; called by mutect2, pindel, varscan2
- KCNK9 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV100270977; called by muse, mutect2, varscan2
- KCNT2 | c.1826C>A p.A609E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99653618; called by muse, mutect2, varscan2
- KIF1A | c.4808G>T p.R1603L (on ENST00000320389 / NM_001379639.1; = p.R1595L on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100240907, COSV100240915; called by muse, mutect2, varscan2
- KIF22 | c.1948A>C p.K650Q | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV99361126; called by muse, mutect2, varscan2
- KLC3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV101228888; called by muse, mutect2
- KLC3 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV101228889; called by muse, mutect2
- LAMC1 | c.3259C>T p.R1087C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs769737749, COSV51132563; called by muse, mutect2
- LCOR | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV53714375; called by muse, mutect2, varscan2
- LILRA2 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV99253364; called by muse, mutect2, varscan2
- LMO2 | c.370G>T p.A124S (on ENST00000395833 / NM_001142315.2; = p.A193S on NM_005574.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.584); catalogued as rs781133624, COSV57645556, COSV99063103; called by muse, mutect2
- LONP1 | c.2819G>A p.R940Q | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as rs558125416; called by muse, mutect2, varscan2
- LRP1B | c.8567G>C p.R2856P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101256763, COSV67191728; called by muse, mutect2, varscan2
- LRP1B | c.3745G>T p.G1249C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101256765, COSV67263818; called by muse, mutect2, varscan2
- LRP1B | c.1106C>A p.T369K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101256767; called by muse, mutect2, varscan2
- LYST | c.8422G>A p.E2808K | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV101089344; called by muse, mutect2, varscan2
- LYST | c.5890C>T p.H1964Y | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as rs907054312, COSV101089345; called by muse, mutect2
- MAP2 | c.1727C>G p.S576C | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52288640, COSV99559897; called by muse, mutect2
- MBOAT1 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100208808, COSV61123667; called by muse, mutect2, varscan2
- MC2R | c.892T>A p.*298Kext*3 | Nonstop Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV100562997; called by muse, mutect2, varscan2
- ME1 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | catalogued as COSV100866513; called by muse, mutect2, varscan2
- MED12 | c.5162A>T p.Q1721L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100377954; called by muse, mutect2, varscan2
- MEX3A | c.1048G>T p.G350C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as COSV101348935; called by muse, mutect2, varscan2
- MMP13 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); catalogued as COSV99506541; called by muse, mutect2, varscan2
- MRS2 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as rs1240715252, COSV99218929; called by muse, mutect2, varscan2
- MTOR | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.831); catalogued as COSV100816170, COSV63868239; called by muse, mutect2
- MUC13 | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1454940075, COSV100222337; called by muse, mutect2
- NDUFA12 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100580853; called by muse, mutect2, varscan2
- NFRKB | c.2744G>T p.G915V (on ENST00000446488 / NM_001143835.2; = p.G940V on NM_006165.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100451904; called by muse, mutect2
- NKD2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs199906392; called by muse, mutect2, varscan2
- NLRP2 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771360716, COSV99672264; called by muse, mutect2, varscan2
- NOTCH1 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53045690, COSV53058447; called by muse, mutect2
- NPAP1 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV61504711; called by muse, mutect2, varscan2
- OBSCN | c.14614A>G p.M4872V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1558329337, COSV99477709; called by muse, mutect2
- OFD1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV100406911; called by muse, mutect2, varscan2
- OR2A12 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV101283167; called by muse, mutect2
- OR2T6 | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100861564; called by muse, mutect2, varscan2
- OR52L1 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100176169; called by muse, mutect2, varscan2
- OR5T1 | c.53T>A p.F18Y | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100478962, COSV57302217; called by muse, mutect2, varscan2
- OR9G1 | c.805A>T p.M269L | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100380402; called by muse, mutect2, varscan2
- PAK5 | c.1244G>T p.S415I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100780952; called by mutect2, varscan2
- PAPOLG | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53184435; called by muse, mutect2
- PCDHA13 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as rs530412188, COSV56497801; called by muse, mutect2, varscan2
- PCDHA2 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV65366738, COSV65370404; called by muse, mutect2, varscan2
- PCDHGA10 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99538085; called by muse, mutect2
- PDE2A | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100557955; called by muse, mutect2, varscan2
- PEX1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV99952103; called by muse, mutect2, varscan2
- PFKM | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100402494; called by muse, mutect2, varscan2
- PGLYRP4 | c.824A>T p.N275I | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100668401; called by muse, mutect2, varscan2
- PHACTR3 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs143127476, COSV100732582; called by muse, mutect2, varscan2
- PHKB | c.330G>T p.R110S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100067025; called by muse, mutect2
- PKD2L1 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as rs868223368, COSV58395172, COSV58398876; called by muse, mutect2, varscan2
- PLAUR | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99655151; called by muse, mutect2
- PLCH1 | c.4093G>A p.E1365K (on ENST00000340059 / NM_001130960.2; = p.E1357K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV100396828; called by muse, mutect2, varscan2
- PLEKHG1 | c.4114C>G p.L1372V | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100651621; called by muse, mutect2
- POLA1 | c.2122C>G p.L708V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100985416; called by muse, mutect2
- PPP2R1A | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59045522; called by muse, mutect2
- PPP2R2A | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100277180; called by muse, mutect2, varscan2
- PPRC1 | c.1154C>G p.S385C | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV99531657; called by muse, mutect2
- PRAMEF4 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52440324, COSV99339826; called by muse, mutect2, varscan2
- PSG11 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.055); catalogued as rs1379532215, COSV100105806; called by muse, mutect2, varscan2
- PSG2 | c.571C>G p.H191D | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as rs753705992, COSV100283519; called by muse, mutect2
- PTF1A | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100919583; called by muse, mutect2, varscan2
- RAB3IP | c.1354C>G p.Q452E (on ENST00000550536 / NM_175623.4; = p.Q436E on NM_022456.5) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV99923206, COSV99923775; called by muse, mutect2, varscan2
- RBM10 | c.2101-1G>A p.X701_splice | Splice Site (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100237785; called by muse, mutect2, varscan2
- RP1L1 | c.5854G>T p.G1952W | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV101223233; called by muse, mutect2
- RPS4X | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100289072; called by muse, mutect2, varscan2
- RRP12 | c.3199C>G p.Q1067E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1007686872, COSV100213173; called by muse, mutect2
- SETBP1 | c.3419C>G p.A1140G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99953270, COSV99955645; called by muse, mutect2, varscan2
- SHROOM2 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66605067; called by muse, mutect2, varscan2
- SLC27A3 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV99669930; called by muse, mutect2
- SLC4A8 | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100176874, COSV100176995; called by muse, mutect2
- SLF2 | c.3520T>C p.*1174Qext*1 | Nonstop Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99489172; called by muse, mutect2, varscan2
- SOX6 | c.1465C>G p.L489V (on ENST00000528429 / NM_001145819.2; = p.L462V on NM_017508.3) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV100322158, COSV57046922; called by muse, mutect2, varscan2
- SPATA12 | c.103A>T p.R35* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100534689; called by muse, mutect2, varscan2
- SPEF2 | c.1019G>C p.R340P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99214207, COSV99214224; called by muse, mutect2, varscan2
- SPEF2 | c.1430C>G p.S477C | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV56799781, COSV99214211; called by muse, mutect2, varscan2
- STK16 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99850521; called by muse, mutect2, varscan2
- STK26 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100688719, COSV100688761; called by muse, mutect2
- SVEP1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100237987; called by muse, mutect2, varscan2
- SVEP1 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237989; called by muse, mutect2, varscan2
- TAF2 | c.2073C>A p.F691L | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100978680; called by muse, mutect2, varscan2
- TANC1 | c.3994A>G p.N1332D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV99713908; called by muse, mutect2, varscan2
- TET2 | c.3169G>T p.E1057* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as rs202118034, COSV54416085; called by muse, mutect2, varscan2
- TIMP4 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.344); catalogued as COSV99826012; called by muse, mutect2
- TLR7 | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101027873; called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as rs758492571, COSV99547246; called by muse, mutect2
- TPK1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100765668; called by muse, mutect2, varscan2
- TPTE2 | c.986C>T p.T329I (on ENST00000400230 / NM_199254.2; = p.T252I on NM_130785.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99690310; called by muse, mutect2, varscan2
- TRPM5 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50144405; called by muse, mutect2, varscan2
- TUFT1 | c.237G>A p.K79= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100777064; called by muse, mutect2, varscan2
- TULP1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100004142; called by muse, mutect2
- UCHL1 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV99449123; called by muse, mutect2, varscan2
- USP32 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100341994; called by muse, mutect2, varscan2
- UTP14A | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV64086744, COSV64086807; called by muse, mutect2
- UTP14C | c.937A>T p.K313* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV101584292; called by muse, mutect2, varscan2
- VCAN | c.8797C>A p.Q2933K | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99425703; called by muse, mutect2
- VEPH1 | c.1427G>C p.S476T | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100747560; called by muse, mutect2
- WDR31 | c.244G>C p.D82H (on ENST00000374193 / NM_001006615.3; = p.D81H on NM_145241.5) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100516691; called by muse, mutect2, varscan2
- WDR49 | c.967G>C p.D323H (on ENST00000308378 / NM_001366158.1; = p.D664H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100392728; called by muse, mutect2, varscan2
- ZNF208 | c.3689G>T p.C1230F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101237020; called by muse, mutect2, varscan2
- ZNF24 | c.726G>C p.K242N | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV99734267; called by muse, mutect2, varscan2
- ZNF367 | c.421-2A>C p.X141_splice | Splice Site (SNP) | VAF 35/109 reads (32%) | catalogued as COSV100930854; called by muse, mutect2, varscan2
- ZNF433 | c.626T>C p.F209S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100794997, COSV61399285; called by muse, mutect2, varscan2
- ZNF433 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100794998; called by muse, mutect2
- ZNF484 | c.1979G>C p.G660A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100214652; called by muse, mutect2, varscan2
- ZNF536 | c.1471T>A p.C491S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV100835228; called by muse, mutect2, varscan2
- ZNF543 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs760512176, COSV100386762; called by muse, mutect2, varscan2
- ZRANB3 | c.2596C>G p.P866A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99923595; called by muse, mutect2, varscan2
- BBS12 | c.211_212insG p.N71Rfs*2 | Frame Shift Ins (INS) | VAF 11/79 reads (14%) | called by mutect2, pindel*
- CERT1 | c.702_704dup p.Q235dup (on ENST00000405807 / NM_001130105.1; = p.Q107dup on NM_005713.3) | In Frame Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- DPY19L2 | c.409del p.L137Sfs*8 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- KLHL15 | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- PAK5 | c.1242del p.S415Afs*63 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- RIPOR3 | c.2186del p.G729Dfs*5 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2
- SSH2 | c.779_782del p.E260Afs*2 | Frame Shift Del (DEL) | VAF 4/51 reads (8%) | called by mutect2, pindel
- SUPT20HL1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TEP1 | c.3865del p.R1289Gfs*7 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- ACAT1 | c.183G>A p.L61= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99759230; called by muse, mutect2, varscan2
- ALS2 | c.4464G>T p.P1488= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs906376097, COSV51892825; called by muse, mutect2, varscan2
- C1QTNF9 | c.627G>T p.T209= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV100129896; called by muse, mutect2, varscan2
- CAMTA2 | c.2877C>T p.F959= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs982611360, COSV52780562; called by muse, mutect2
- CMYA5 | c.10314A>T p.S3438= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101484043; called by muse, mutect2, varscan2
- CNTN4 | c.2403C>T p.P801= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100639244; called by muse, mutect2, varscan2
- COL15A1 | c.4053A>G p.G1351= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100897660; called by muse, mutect2, varscan2
- CTTNBP2 | c.1569A>T p.P523= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV99353918; called by muse, mutect2, varscan2
- DISP3 | c.3855C>T p.A1285= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs779255682, COSV53838065; called by muse, mutect2, varscan2
- DMGDH | c.654A>T p.P218= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as COSV99668965; called by muse, mutect2, varscan2
- DOCK2 | c.2100C>A p.I700= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV99912353; called by muse, mutect2, varscan2
- EPHB1 | c.2487C>T p.S829= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as COSV101213158; called by muse, mutect2, varscan2
- F8 | c.4443G>A p.L1481= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV100811518; called by muse, mutect2
- FSHB | c.156C>A p.T52= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99569405; called by muse, mutect2
- GPR101 | c.570C>A p.P190= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV53239290, COSV99981414; called by muse, mutect2, varscan2
- GRIP1 | c.2514G>A p.R838= (on ENST00000359742 / NM_001379345.1; = p.R786= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/215 reads (5%) | catalogued as COSV99669402; called by muse, mutect2
- KRT13 | c.990C>A p.G330= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV99877352; called by muse, mutect2, varscan2
- LHFPL5 | c.126C>T p.A42= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV100798969; called by muse, mutect2, varscan2
- LRP1B | c.5109C>A p.V1703= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV101256764, COSV67273405; called by muse, mutect2, varscan2
- LRRFIP2 | c.1759C>T p.L587= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100368373; called by muse, mutect2, varscan2
- NBAS | c.4011C>G p.L1337= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV99869582; called by muse, mutect2, varscan2
- NCOR1 | c.4446G>T p.R1482= | Silent (SNP) | VAF 9/193 reads (5%) | catalogued as COSV99249833; called by muse, mutect2
- NRBP2 | c.1482C>G p.L494= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100589208; called by muse, mutect2
- OR5H15 | c.78C>A p.P26= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as COSV100736665; called by muse, mutect2, varscan2
- OR5I1 | c.252G>C p.L84= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100041420; called by muse, mutect2, varscan2
- PEX2 | c.141G>T p.G47= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100824779; called by muse, mutect2, varscan2
- PLB1 | c.2199G>C p.L733= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100215097; called by muse, mutect2, varscan2
- PLEKHG2 | c.1114C>A p.R372= | Silent (SNP) | VAF 20/304 reads (7%) | catalogued as COSV99216934, COSV99217429; called by muse, mutect2
- PLXNA4 | c.3411C>A p.T1137= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV100324223; called by muse, mutect2, varscan2
- PRKCSH | c.1380C>T p.F460= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV99371588; called by muse, mutect2, varscan2
- SART1 | c.1087C>A p.R363= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100409011; called by muse, mutect2, varscan2
- SLC25A2 | c.240C>G p.V80= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs782193527, COSV99508246; called by muse, mutect2, varscan2
- SLC6A7 | c.1776G>T p.V592= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100046277; called by muse, mutect2, varscan2
- SYCP2 | c.3615G>T p.L1205= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100698249; called by muse, mutect2
- TIMP4 | c.51G>A p.L17= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV55138746, COSV99826014; called by muse, mutect2
- TTC16 | c.12G>C p.S4= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100076871; called by muse, mutect2
- ZIK1 | c.343C>T p.L115= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV100277483; called by muse, mutect2
- ZNF585A | c.1755A>G p.R585= (on ENST00000292841 / NM_001288800.2; = p.R530= on NM_152655.3) | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- PYY3 | n.140A>G | RNA (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895956 G>A | 5'Flank (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100019176; called by muse, mutect2, varscan2
- RRAGD | c.*2T>A | 3'UTR (SNP) | VAF 41/124 reads (33%) | catalogued as COSV100784555; called by muse, mutect2, varscan2
- SNORD115-30 | n.81C>T | RNA (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
